Surgical pathology report (de-identified scan), TCGA case TCGA-55-7283, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7283-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Lung, right middle lobe; wedge resection:
Multiple microscopic foci of adenocarcinoma measuring up to 0.3 cm in greatest dimension individually.
Hamartoma, 1.1 cm in greatest dimension.
Tumor foci present in subpleural lymphatics.

B. Lung, right upper lobe; lobectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: Moderately to poorly differentiated.
3. Tumor site: Right upper lobe.
4. Tumor focality: Multifocal.
5. Tumor size: 7.5 x 5.5 x 3.8 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Present.
8. Tumor extension: Tumor limited to pulmonary parenchyma.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 0.2 cm.
2. Two foci of bronchioloalveolar carcinoma in the en face parenchymal margin.
3. Tumor distance from pleural surface: Less than 0.1 cm.

Lymph Node Status:

1. Total number of lymph nodes received: 5
Four peribronchial nodes.
One level eight node, see specimen C.
2. Total number of lymph nodes containing metastatic carcinoma: 3 (3/5).
Two positive peribronchial nodes.
One positive level 8 node.

Other:

1. pTNM stage: pT3 N2.
2. Bronchioloalveolar carcinoma associated with invasive adenocarcinoma.

C. Lymph node, level 8; excision:

Metastatic adenocarcinoma present in one lymph node (1/1).

Electronic Signature

COMMENTS:

Histologic sections from the right middle lobe wedge show a hamartoma, as seen in the frozen section slide. However, in addition to this finding, there are microscopic foci in sections not examined at the time of frozen section. These foci measure up to 0.3 cm in greatest dimension individually. In addition, this section in slide A4 also shows multiple microscopic foci of tumor within subpleural lymphatic spaces.

The main tumor in the right upper lobe is that of an adenocarcinoma which is moderately to poorly differentiated. Two foci of bronchioloalveolar carcinoma are also present in the shaved parenchymal margin. Multiple positive nodes are present.

Current NCCN practice guidelines recommend determination of EGFR and KRAS mutation status in adenocarcinoma of lung to help select patients for Tyrosine-Kinase Inhibitor (TKI) therapy. EGFR-activating mutations have been shown to be significantly associated with response to TKIs and KRAS mutations are associated with TKI resistance. They are mutually exclusive in NSCLC. Additionally, recent data show that ALK (Anaplastic Lymphoma Kinase) gene rearrangements in adenocarcinoma of lung are associated with resistance to TKIs and have favorable response rates to Crizotinib, the ALK inhibitor agent currently in clinical trials. Mutation analysis for KRAS and EGFR-TK domain and ALK gene rearrangement by FISH is available as the

[page 2 of 2]
[REDACTED]

Lung Cancer Mutation Panel. Testing may be performed on paraffin-embedded tissue from the primary or metastatic tumor or pleural fluid cell block. These tests are available on request as a panel or as individual assays.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] old female with right sided pulmonary nodule suspicious for malignancy with increased SUV.

Postoperative Diagnosis: Left side of excisional biopsy of histoplasmosis lung in [REDACTED]

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right middle lobe wedge with frozen section.
- B. Right upper lobe lung.
- C. Level 8 lymph node.

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A specimen is received in three containers labeled [REDACTED]. Container A is labeled right middle lobe wedge and contains a 5.0 x 3.0 x 1.8 cm lung wedge. The pleura is purple-gray and glistening. The staple line is removed and the underlying parenchyma is inked black. Specimen is sectioned to reveal a 1.1 x 0.9 x 0.8 cm well circumscribed yellow-tan nodule that approaches to within 0.1 cm in the inked margin. The remainder of the parenchyma is pink-tan and spongy. There is no additional lesions. Representative sections from the nodule are submitted for frozen section with the residual entirely resubmitted for permanent section in cassette A1 labeled [REDACTED]. Additional representative sections are submitted in cassettes A2-A4 to include the remainder of the nodule in cassette A2.

B. Container B is additionally labeled right upper lobe and contains a 10.0 x 8.5 x 5.0 cm lung lobe. A 6.0 x 3.5 cm aggregate of exposed parenchyma with multiple segments of exposed vasculature and bronchi are identified. Extending from one end of the exposed parenchyma are two serpiginous staple lines 4.5 cm each. Pleura is purple-pink and glistening with a 3.0 x 3.0 cm area of umbilication. This area is inked black and the specimen is serially sectioned to reveal a 7.5 x 5.5 x 3.8 cm defined yellow-tan mass that abuts the pleura at the site of umbilication and approaches to within a 0.2 cm of the exposed parenchyma, vasculature and bronchial margins. Additionally, this mass approaches to within 2.5 cm of the stapled parenchyma. The uninvolved parenchyma is beefy red and spongy. No additional masses are identified. Representative sections are submitted in cassettes B1-B10 labeled [REDACTED] designated as follows: B1-B2 enface of sections of exposed vascular and parenchymal margins; B3-B4 mass to exposed parenchymal margin, perpendicular; B5 stapled parenchymal margin; perpendicular, B6-B7 mass to umbilicated pleura; B8-B9 additional mass; B10 uninvolved parenchyma. Additionally, a yellow-green and blue cassette are submitted for [REDACTED] research each labeled [REDACTED].

C. Container C is additionally labeled level 8 lymph node and contains a 2.0 cm pink-gray rubbery nodule consistent with lymph node. It is trisected to reveal a gray-white friable cut surface consistent with tumor. The specimen is entirely submitted in cassette C labeled [REDACTED].

INTRA-OPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS: Favor hamartoma per Dr. [REDACTED]

Source: NCI Genomic Data Commons file ba2e5087-610e-4485-adeb-53c442e88a11 (TCGA-55-7283.39929FE3-B87C-413C-8613-F5A15B407B28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).